Somatic mutation profile of tumor specimen TCGA-4G-AAZG-01A (aliquot TCGA-4G-AAZG-01A-11D-A46P-09) from TCGA case TCGA-4G-AAZG, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 75.3 years (27,490 days).
Specimen TCGA-4G-AAZG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cba40d28-05b2-4355-825b-ff55843bffd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4G-AAZG-10A (Blood Derived Normal), aliquot TCGA-4G-AAZG-10A-01D-A46P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/147131e9-a72b-4f6f-ab31-f9f098b3cd66

The open-access MAF lists 83 somatic variants for this specimen: 64 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 17, Nonsense Mutation 10, Frame Shift Ins 3, Frame Shift Del 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KANSL1 | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as rs281865469, CM124328, COSV52265197, COSV52273519; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMBRA1 | c.2056G>A p.E686K (on ENST00000458649 / NM_001367468.1; = p.E596K on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.664); catalogued as COSV54055538; called by muse, mutect2, varscan2
- ARID1A | c.2667del p.M890* | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | catalogued as COSV100253836; called by mutect2, pindel, varscan2
- BRK1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1297077239; called by muse, mutect2, varscan2
- CADM2 | c.622G>A p.E208K (on ENST00000407528 / NM_001167674.2; = p.E210K on NM_153184.4) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.793); catalogued as rs201652066, COSV67409614; called by muse, mutect2, varscan2
- CLGN | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs545177462, COSV57773922; called by muse, mutect2, varscan2
- CNTD1 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs766100218, COSV55911139; called by muse, mutect2, varscan2
- DTL | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs557946653, COSV65342864; called by mutect2, varscan2
- ELF1 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs766771438; called by muse, mutect2, varscan2
- EPHA2 | c.273dup p.E92* | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | catalogued as COSV100626204; called by mutect2, pindel, varscan2
- FGFR2 | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV60647057, COSV60653143; called by muse, mutect2, varscan2
- FLT3 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV54052462; called by muse, mutect2, varscan2
- NEB | c.18400C>G p.Q6134E | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.953); catalogued as rs1297718667; called by muse, mutect2, varscan2
- OR4K17 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV100210637; called by muse, mutect2, varscan2
- PDZRN3 | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1240349665; called by muse, mutect2
- PHLDB3 | c.1341C>A p.S447R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52669412; called by muse, mutect2
- PLXNB2 | c.429C>A p.F143L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV63783375, COSV63784195; called by mutect2, varscan2
- POLR2B | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); catalogued as COSV58900925; called by muse, mutect2, varscan2
- RNF213 | c.13715G>A p.R4572Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs768367050, COSV60395855; called by muse, mutect2, varscan2
- SPTAN1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 33/94 reads (35%) | catalogued as COSV63989520; called by muse, mutect2, varscan2
- TMTC1 | c.479C>T p.A160V (on ENST00000539277 / NM_001193451.2; = p.A52V on NM_175861.3) | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779339155, COSV55488366, COSV99758642; called by muse, mutect2, varscan2
- UBE3D | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as COSV52708331; called by muse, mutect2, varscan2
- USP42 | c.3298C>T p.R1100C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs1405508137; called by muse, mutect2
- USP6 | c.2306A>C p.D769A | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.082); catalogued as rs1224435711; called by muse, mutect2
- ZNF536 | c.3758G>A p.R1253Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs755711056, COSV62824835; called by muse, mutect2
- AKAP6 | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ANKK1 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- BRAP | c.1203dup p.D402Rfs*38 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- BTBD3 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC42 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DACH2 | c.525C>G p.N175K | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ERC1 | c.2929C>T p.Q977* (on ENST00000360905 / NM_178040.4; = p.Q949* on NM_178039.4) | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- FAM71D | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- FOXG1 | c.1228C>A p.L410I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- GRK5 | c.18C>G p.I6M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); called by mutect2, varscan2
- INO80 | c.2209A>G p.M737V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- KMT2D | c.506C>G p.S169* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- LYST | c.335C>G p.S112* | Nonsense Mutation (SNP) | VAF 28/118 reads (24%) | called by muse, mutect2, varscan2
- MAP2K4 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- MCC | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- MSX2 | c.420G>C p.K140N | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYH8 | c.3523C>T p.Q1175* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- MYLK | c.4636C>A p.L1546M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NEDD1 | c.870C>G p.H290Q | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NPBWR1 | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.699); called by muse, mutect2
- NSD2 | c.3083_3084insC p.D1029* | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | called by mutect2, pindel, varscan2
- OPCML | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.405); called by muse, mutect2
- OR1E2 | c.142C>A p.L48I | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PALLD | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PCDHA1 | c.2191G>A p.A731T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PNMA3 | c.788A>C p.K263T | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PROSER1 | c.647C>A p.A216D | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTGER3 | c.374C>G p.P125R | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- RAB31 | c.464A>T p.N155I | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIOX2 | c.66G>T p.M22I | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RLF | c.1448T>A p.L483* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- SGCE | c.836A>T p.Q279L (on ENST00000647096; = p.Q243L on NM_003919.3) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- SNX7 | c.1226T>C p.I409T | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SREBF2 | c.754T>C p.S252P | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TLR6 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPD52L3 | c.315C>G p.I105M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- TSHR | c.1215del p.F405Lfs*7 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, varscan2
- UBE4B | c.2324G>C p.R775P (on ENST00000343090 / NM_001105562.3; = p.R646P on NM_006048.5) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZSWIM2 | c.1524A>G p.I508M | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APBB1 | c.1239T>C p.S413= | Silent (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- CAPN13 | c.1275G>A p.V425= | Silent (SNP) | VAF 9/131 reads (7%) | catalogued as rs745391633; called by muse, mutect2
- CCDC3 | c.492G>A p.S164= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs770704967, COSV66561316; called by muse, mutect2, varscan2
- CLTCL1 | c.1356G>A p.L452= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- COL23A1 | c.1542C>T p.G514= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as rs551123931, COSV66790948, COSV66794765; called by muse, mutect2, varscan2
- CPA1 | c.819G>A p.E273= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- CRYBG1 | c.1833C>G p.A611= | Silent (SNP) | VAF 37/152 reads (24%) | called by muse, mutect2, varscan2
- DCC | c.171C>T p.V57= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs911570615; called by muse, mutect2, varscan2
- EIF2AK2 | c.759A>G p.K253= | Silent (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2
- EXOC1 | c.1992A>G p.S664= | Silent (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- GGTLC2 | c.618C>T p.A206= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs760518029; called by muse, mutect2, varscan2
- GLI3 | c.3705C>T p.P1235= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs138618219; called by muse, mutect2, varscan2
- MPP5 | c.1548G>A p.R516= | Silent (SNP) | VAF 25/103 reads (24%) | called by muse, mutect2, varscan2
- SEC16B | c.1257G>A p.L419= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV100381688; called by muse, mutect2, varscan2
- ZC3H12C | c.1206G>A p.L402= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as rs766311382, COSV53706154; called by muse, mutect2, varscan2
- ZNF573 | c.471C>T p.V157= (on ENST00000536220 / NM_001172692.1; = p.V99= on NM_152360.3) | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- ZNF835 | c.537G>A p.S179= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV73379684; called by muse, mutect2, varscan2
- NR2E1 | c.25+1282C>T | Intron (SNP) | VAF 15/124 reads (12%) | catalogued as COSV64562018; called by muse, mutect2, varscan2
- RGPD1 | c.48+5896G>A | Intron (SNP) | VAF 18/139 reads (13%) | catalogued as COSV101233567; called by muse, mutect2, varscan2
